Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8QM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8QM-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of uterine cervix:

- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C53.9

7/3 12/10/13

Diagnosis Inconsistency		☒
HR-RA Discrepancy		☒

Source: NCI Genomic Data Commons file 470478e6-2181-47ef-99f4-0a92a38a415e (TCGA-VS-A8QM.83522ECF-2552-4708-9311-A15C53D436C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).